CPTAC case 04OV008 — Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/244b7d18-3975-45e6-b159-63e634749a3b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Serous adenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC; Prior malignancy: no.

Biospecimens (2 samples)
- Sample cedd3881-6311-4c1d-9e9d-191243: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample efc971f8-54c5-4531-a792-705ecf: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
